CPTAC case SC-0317 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/85eb7340-80e0-45f6-b182-1a12da3070c1

Demographics
Sex at birth: female; Vital status: Dead; Days to death: 517 days (1.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of lower limb and hip; Age at diagnosis: 58.0 years (21,185 days); AJCC staging edition: 8th; AJCC pathologic T: T4b; AJCC pathologic N: N3a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIID; Last known disease status: With tumor; Days to last known disease status: 517 days (1.4 years); Progression or recurrence: yes; Days to recurrence: 457 days (1.3 years); Clark level: IV.
   Pathology details: Breslow thickness: 6.6.

Biospecimens (2 samples)
- Sample S-1803-013834: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 232 mg; Method of sample procurement: Tumor Resection.
- Sample S-1803-013835: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 160 mg; Method of sample procurement: Tumor Resection.
